Somatic mutation profile of tumor specimen TCGA-KB-A6F5-01A (aliquot TCGA-KB-A6F5-01A-12D-A33T-08) from TCGA case TCGA-KB-A6F5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.6 years (26,881 days).
Specimen TCGA-KB-A6F5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bf7c6e9-d1d5-4ced-9def-7ac4d9c41a3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KB-A6F5-10A (Blood Derived Normal), aliquot TCGA-KB-A6F5-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee3e4bc2-cbc1-4443-8d9e-bfa8a28558be

The open-access MAF lists 69 somatic variants for this specimen: 47 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 21, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>G p.S215R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520001, CD941799, COSV52752255, COSV52783847, COSV52798196; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ASH1L | c.6617G>C p.G2206A (on ENST00000368346 / NM_001366177.2; = p.G2201A on NM_018489.3) | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as COSV100853617; called by muse, mutect2, varscan2
- BTK | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as CM056547, COSV100437965; called by muse, varscan2
- BUB1B | c.2939T>C p.L980P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99807393; called by muse, mutect2, varscan2
- CD163 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs762652679, COSV100776170; called by muse, mutect2, varscan2
- CILP | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs376689702; called by muse, mutect2, varscan2
- CNR2 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100991623; called by muse, mutect2, varscan2
- CXorf58 | c.216G>A p.A72= | Splice Region (SNP) | VAF 66/123 reads (54%) | catalogued as rs760447315, COSV101003124; called by muse, mutect2, varscan2
- CYFIP2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs763631624, COSV59027557; called by muse, mutect2, varscan2
- EDA | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100999633; called by muse, mutect2, varscan2
- EPHA8 | c.2653T>C p.F885L | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV99385827; called by muse, mutect2, varscan2
- ESS2 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV99351290; called by muse, mutect2, varscan2
- ESS2 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.982); catalogued as rs1457810365, COSV99351291; called by muse, mutect2, varscan2
- FAM78A | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV99908628; called by muse, mutect2, varscan2
- FBXW7 | c.916C>T p.Q306* (on ENST00000281708 / NM_001349798.2; = p.Q226* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV55898870, COSV55906031, COSV55913059; called by muse, mutect2, varscan2
- GDF6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54624691; called by muse, mutect2, varscan2
- GPR25 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV58498204; called by muse, mutect2, varscan2
- IGSF3 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as rs767125045, COSV59598070; called by mutect2, varscan2
- IL10RA | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199989396, CM134627, COSV99923295; called by muse, mutect2, varscan2
- KLHL26 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as COSV56318327; called by muse, mutect2, varscan2
- LRATD1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99707314; called by muse, mutect2, varscan2
- LVRN | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1451691992, COSV100773701; called by muse, mutect2, varscan2
- MKKS | c.601A>C p.I201L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.179); catalogued as COSV100726330; called by muse, mutect2, varscan2
- MRGPRX2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV61674905; called by muse, mutect2, varscan2
- MYBL1 | c.1825T>C p.Y609H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.903); catalogued as COSV101576615; called by muse, mutect2, varscan2
- NACC1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99457344; called by muse, mutect2, varscan2
- NAV3 | c.4364C>A p.T1455N | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99896261; called by muse, mutect2, varscan2
- NBEA | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV100084750; called by muse, mutect2
- NR5A1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.261); catalogued as CM147767, COSV65295779; called by muse, mutect2, varscan2
- PKP3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs759359764, COSV100520964; called by muse, mutect2, varscan2
- PRICKLE2 | c.1280C>T p.P427L (on ENST00000295902; = p.P371L on NM_198859.4) | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99898153; called by muse, mutect2, varscan2
- PTHLH | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV52366735; called by muse, mutect2, varscan2
- RALGAPA1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99356307; called by muse, mutect2, varscan2
- RPH3A | c.2026G>T p.D676Y (on ENST00000389385 / NM_001143854.2; = p.D672Y on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101231905, COSV66992469; called by muse, mutect2, varscan2
- SP140 | c.978G>A p.E326= | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as COSV100614138; called by muse, mutect2, varscan2
- SPTBN2 | c.5006A>C p.Q1669P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020609; called by muse, mutect2, varscan2
- SRA1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1210131221, COSV99784659; called by muse, mutect2, varscan2
- ST6GAL2 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | PolyPhen benign (0.07); catalogued as COSV100868311; called by muse, varscan2
- TCHP | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs141514320; called by muse, mutect2, varscan2
- TNFSF11 | c.843T>A p.F281L | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs1566391626, COSV99520751; called by muse, mutect2, varscan2
- UNC5D | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.916); catalogued as rs374013131; called by muse, mutect2, varscan2
- ZFR2 | c.395G>C p.C132S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99507976; called by muse, mutect2, varscan2
- ZNF569 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 106/563 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100386669; called by muse, mutect2, varscan2
- ASPA | c.484dup p.L162Pfs*29 | Frame Shift Ins (INS) | VAF 41/121 reads (34%) | called by mutect2, pindel, varscan2
- IL1RAPL2 | c.764dup p.Q256Pfs*4 | Frame Shift Ins (INS) | VAF 35/76 reads (46%) | called by mutect2, pindel, varscan2
- MED23 | c.2096del p.D699Vfs*22 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- OASL | c.-1_1del | Translation Start Site (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- ASH1L | c.6618G>T p.G2206= (on ENST00000368346 / NM_001366177.2; = p.G2201= on NM_018489.3) | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV100853616; called by muse, mutect2, varscan2
- BEST3 | c.1377C>T p.S459= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as rs545255599, COSV100438077; called by muse, mutect2, varscan2
- C5orf24 | c.336C>T p.T112= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV100574592; called by muse, mutect2
- CCDC93 | c.72T>C p.N24= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100099576; called by muse, mutect2, varscan2
- CD247 | c.495A>G p.*165= (on ENST00000362089 / NM_198053.3; = p.*164= on NM_000734.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as COSV99612463; called by muse, mutect2, varscan2
- CELSR2 | c.6351C>T p.D2117= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99604857; called by muse, mutect2
- CFAP45 | c.399G>A p.K133= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV63649779; called by muse, mutect2, varscan2
- CSMD1 | c.6066C>T p.T2022= (on ENST00000520002; = p.T2021= on NM_033225.6) | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs374372985, COSV59308087; called by muse, mutect2, varscan2
- CYP4F3 | c.1230C>T p.D410= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs766845413, COSV55407927; called by muse, mutect2, varscan2
- DOCK6 | c.2730G>A p.E910= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99626838; called by muse, mutect2, varscan2
- FCGBP | c.8805C>T p.V2935= | Silent (SNP) | VAF 38/223 reads (17%) | catalogued as rs1462423362; called by muse, mutect2, varscan2
- LBP | c.870C>T p.S290= | Silent (SNP) | VAF 61/303 reads (20%) | catalogued as COSV54143957, COSV99461407; called by muse, mutect2, varscan2
- LRRIQ1 | c.1464A>C p.A488= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101280733; called by muse, mutect2, varscan2
- NALCN | c.3036C>T p.S1012= | Silent (SNP) | VAF 110/186 reads (59%) | catalogued as rs760941305, COSV99218122; called by muse, mutect2, varscan2
- NOTCH1 | c.4596C>T p.Y1532= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs751774685, COSV53039312; called by muse, mutect2, varscan2
- NOX5 | c.867C>T p.L289= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV52987410; called by muse, mutect2, varscan2
- NPAP1 | c.2208C>T p.S736= | Silent (SNP) | VAF 30/206 reads (15%) | catalogued as rs758464262, COSV61505318; called by muse, mutect2, varscan2
- SH3PXD2B | c.2190G>A p.P730= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs758320891, COSV100288603; called by muse, mutect2, varscan2
- TFAP2D | c.826T>C p.L276= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as COSV99147357, COSV99148083; called by muse, mutect2, varscan2
- TRAPPC11 | c.2610T>C p.I870= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100592066; called by muse, mutect2, varscan2
- TRPM4 | c.1623G>A p.S541= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV99421035; called by muse, mutect2, varscan2
- OR2T1 | c.-7A>G | 5'UTR (SNP) | VAF 47/142 reads (33%) | catalogued as COSV100822360; called by muse, mutect2, varscan2
